Surgical pathology report (de-identified scan), TCGA case TCGA-UW-A72P, project TCGA-KICH (Kidney Chromophobe), tissue source site University of North Carolina, specimen TCGA-UW-A72P-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

1CD-0-3

Case Number:

Diagnosis:

A: Kidney, right, partial nephrectomy

Procedure: partial nephrectomy

Laterality: right

Histologic tumor type/subtype: eosinophilic variant of chromophobe renal cell carcinoma

Sarcomatoid features: absent

Histologic grade (if applicable): Fuhrman 2 (of 4)

Tumor size (greatest dimension): 3.8 cm, gross measurement

Tumor focality: unifocal

Extent of tumor invasion (if present specify if macroscopic or microscopic):

Capsular invasion/perirenal adipose tissue: tumor invades into but not through the renal capsule, does not involve perirenal adipose tissue

Gerota's fascia: not applicable

Renal sinus: not applicable

Major veins (renal vein or segmental branches, IVC): not applicable

Ureter: not applicable

Venous (large vessel): absent

Lymphatic (small vessel): absent

Histologic assessment of surgical margins:

Renal parenchymal margin (partial nephrectomy only): negative but close, tumor is <1 mm from the black inked parenchymal margin (blocks A2, A3)

Renal capsular margin (partial nephrectomy only): negative but close, tumor is <1 mm from the blue inked capsular margin (A4)

Paranephric adipose tissue margin (partial nephrectomy only): not applicable, no perinephric adipose tissue present in specimen

Carcinoma, renal cell

chromophobe type 8317/3

Site: (R) Kidney, NIS C64.9

*fw
8/6/13*

[page 2 of 3]
Adrenal gland: not present in specimen

Lymph nodes: none present in specimen

Pathologic findings in non-neoplastic kidney: no specific pathologic abnormalities

AJCC Staging:

pT1a

pNx

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Clinical History:

-year-old female with right renal mass.

Gross Description:

Received is one appropriately labeled container, additionally labeled "right renal mass partial nephrectomy."

Specimen fixation: formalin

Type of specimen: partial

Side of specimen: right

Size and weight of specimen: 45.7 grams, 5.5 x 5.0 x 4.4 cm

Orientation: The capsule is inked blue and the parenchymal margin is inked black.

Presence/absence of adrenal gland: absent

Tumor site: cortical, cortex into medulla

Tumor description: The mass is well circumscribed, encapsulated, friable, tan/pink

Tumor size: 3.8 x 3.6 x 3.4 cm

Presence/absence of multicentricity: Absent

Confinement/non-confinement to the kidney: confined

[page 3 of 3]
Extent of invasion:

Perirenal adipose tissue: grossly does not involve

Gerota' s fascia: grossly does not involve

Renal vein: N/A

Ureter: N/A

Renal Sinus: N/A

Pelviccaliceal: involved

Adrenal: n/a

Other organs: not submitted

Surgical margins: The mass grossly abuts the black inked surgical margin and abuts but does not invade through the capsule margin (blue ink).

Description of kidney away from tumor: The remaining kidney is red/tan with normal architecture.

Hilar lymph nodes: n/a

Other significant findings: none

Tissue submitted for tumor for

Digital picture: not taken

Block summary:

A1-A3 - representative sections of tumor with closest approach to black inked margin

A4 - tumor with closest approach to blue inked capsular margin

A5 - tumor with adjacent normal

A6 - kidney uninvolved by tumor

Tissue remains in formalin.

Source: NCI Genomic Data Commons file 67d125b1-bdbd-4919-960e-e8d4e62454b1 (TCGA-UW-A72P.086608D4-B3A4-437E-BA67-BA51E206D45D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).